Somatic mutation profile of cancer-model specimen HCM-BROD-0334-C43-85M (Adherent Cell Line, passage 13; aliquot HCM-BROD-0334-C43-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0334-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.8 years (25,868 days).
Specimen HCM-BROD-0334-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a10db5ee-35ae-4b64-9fe3-534ef8449ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0334-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0334-C43-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6e48afb-538a-4c2c-96c6-008cdbb3e48b

The open-access MAF lists 1,939 somatic variants for this specimen: 1,254 protein-altering or splice-affecting, 605 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,128, Silent 605, Nonsense Mutation 84, Intron 42, Splice Region 17, 5'Flank 13, Frame Shift Del 10, 3'UTR 9, Splice Site 7, RNA 7, 3'Flank 5, Translation Start Site 4.

Variants (750 of 1,939; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD1 | c.1464G>A p.W488* | Nonsense Mutation (SNP) | VAF 109/292 reads (37%) | catalogued as rs1447749222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.3682C>T p.Q1228* | Nonsense Mutation (SNP) | VAF 111/261 reads (43%) | catalogued as rs1566767820; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 244/244 reads (100%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 149/270 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYBPC3 | c.3083C>T p.T1028I | Missense Mutation (SNP) | VAF 312/645 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs397516002, CM081701, CM143622; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- TIMM8A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 231/231 reads (100%) | catalogued as rs1054894, CM014112, COSV58123662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3194G>A p.R1065K (on ENST00000404938 / NM_001163941.2; = p.R620K on NM_178559.6) | Missense Mutation (SNP) | VAF 178/376 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs754109371; called by muse, varscan2
- ABCB5 | c.3214G>A p.G1072R (on ENST00000404938 / NM_001163941.2; = p.G627R on NM_178559.6) | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770734215, COSV51718192; called by muse, varscan2
- ABLIM1 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 198/198 reads (100%) | catalogued as rs761534863; called by muse, mutect2, varscan2
- AC099489.1 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 446/878 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs904693094; called by muse, mutect2
- AC244197.3 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 340/340 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950670; called by muse, mutect2, varscan2
- ACACB | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 209/463 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1297313839; called by muse, mutect2, varscan2
- ACSM2B | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 128/266 reads (48%) | catalogued as COSV61656697; called by muse, mutect2, varscan2
- ADAD2 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 474/1006 reads (47%) | catalogued as COSV99235543; called by muse, mutect2
- ADAD2 | c.1721C>T p.S574L (on ENST00000315906 / NM_001145400.2; = p.S656L on NM_139174.4) | Missense Mutation (SNP) | VAF 252/543 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs760658968; called by muse, mutect2, varscan2
- ADAM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs201075434; called by muse, mutect2, varscan2
- ADAM22 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55990886; called by muse, mutect2, varscan2
- ADAM29 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 136/268 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.035); catalogued as COSV63665747; called by muse, mutect2, varscan2
- ADAM33 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 153/348 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs147463992; called by muse, mutect2, varscan2
- ADAMTS2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 187/288 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as rs763890617, COSV99200985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL2 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865858893; called by muse, mutect2, varscan2
- ADGRG4 | c.6326C>T p.S2109F | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.35); catalogued as rs905547681; called by muse, mutect2, varscan2
- ADGRV1 | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755180090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AIFM3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 171/370 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as rs751841143, COSV100105102; called by muse, mutect2, varscan2
- AK7 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 107/267 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV50876746; called by muse, mutect2, varscan2
- AKR1D1 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 231/436 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs147768057; called by muse, mutect2, varscan2
- ALPK1 | c.3515G>A p.R1172K | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756641865; called by muse, mutect2, varscan2
- ALS2CL | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 144/350 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs765835852, COSV59672729; called by muse, mutect2, varscan2
- AMTN | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs762457474; called by muse, mutect2, varscan2
- ANK3 | c.7894G>A p.E2632K | Missense Mutation (SNP) | VAF 207/208 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV55053233; called by muse, mutect2, varscan2
- ANKRD30A | c.2854A>G p.S952G (on ENST00000611781; = p.S896G on NM_052997.2) | Missense Mutation (SNP) | VAF 53/53 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV64610492; called by muse, mutect2, varscan2
- ANKRD30A | c.2905C>T p.H969Y (on ENST00000611781; = p.H913Y on NM_052997.2) | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV64614497; called by muse, mutect2, varscan2
- ANKRD30A | c.3599C>T p.P1200L (on ENST00000611781; = p.P1144L on NM_052997.2) | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs761126689, COSV64614472; called by muse, mutect2, varscan2
- ANKRD45 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 239/470 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100322515; called by muse, mutect2, varscan2
- ANXA4 | c.225T>G p.S75R | Missense Mutation (SNP) | VAF 162/342 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV67849532; called by muse, mutect2, varscan2
- AOC1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 218/374 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779732006, COSV62868664; called by muse, mutect2, varscan2
- AP1G1 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55496094; called by muse, mutect2
- APOA4 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 269/653 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as COSV63360038; called by muse, mutect2, varscan2
- APOB | c.13025C>T p.P4342L | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1478038018; called by muse, mutect2, varscan2
- APOBEC3B | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.09); catalogued as rs781419105; called by muse, mutect2, varscan2
- AQP6 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 167/309 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1039226530; called by muse, mutect2, varscan2
- ARHGAP39 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 414/784 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs76422018; called by muse, mutect2, varscan2
- ARHGAP44 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 184/187 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs77850388, COSV52390882; called by muse, mutect2, varscan2
- ARHGEF35 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 113/133 reads (85%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs751447543; called by muse, mutect2, varscan2
- ARHGEF38 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 121/314 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1402408053; called by muse, mutect2, varscan2
- ARID5B | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340574832, COSV54413370; called by muse, mutect2, varscan2
- ARPP21 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs535388566, COSV51802472; called by muse, mutect2, varscan2
- ATG2B | c.4957C>T p.R1653C | Missense Mutation (SNP) | VAF 197/409 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs773625847, COSV55890358; called by muse, mutect2, varscan2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 180/375 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2, varscan2
- ATR | c.4507C>T p.R1503* | Nonsense Mutation (SNP) | VAF 93/199 reads (47%) | catalogued as rs754602382, COSV63387617; called by muse, mutect2, varscan2
- AXDND1 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 136/269 reads (51%) | catalogued as COSV100858564; called by muse, mutect2, varscan2
- BAG4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 115/208 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99781921; called by muse, mutect2, varscan2
- BEND4 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 187/805 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.857); catalogued as rs1028356119; called by muse, mutect2, varscan2
- BIRC6 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 214/455 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760928707; called by muse, mutect2, varscan2
- BOD1L1 | c.5246C>T p.P1749L | Missense Mutation (SNP) | VAF 200/477 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1247577272; called by muse, mutect2, varscan2
- BPIFA2 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53612384; called by muse, mutect2, varscan2
- BRCA1 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 153/302 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs876660005; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRD1 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 162/396 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53458581; called by muse, mutect2, varscan2
- BSN | c.8701C>T p.P2901S | Missense Mutation (SNP) | VAF 213/531 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041283835; called by muse, mutect2, varscan2
- BTC | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs150393238, COSV67547383; called by muse, mutect2, varscan2
- C1QTNF12 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 216/505 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1354156522; called by muse, mutect2, varscan2
- C21orf91 | c.857G>A p.R286Q (on ENST00000284881 / NM_001100420.2; = p.R285Q on NM_017447.4) | Missense Mutation (SNP) | VAF 141/302 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as rs746245395, COSV99515988; called by muse, mutect2, varscan2
- C3 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 221/435 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs753979097, COSV99836637; called by muse, mutect2
- CA1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 123/268 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as COSV56277266, COSV99810133; called by muse, mutect2, varscan2
- CADM2 | c.586G>A p.D196N (on ENST00000407528 / NM_001167674.2; = p.D198N on NM_153184.4) | Missense Mutation (SNP) | VAF 209/379 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101052657; called by muse, mutect2, varscan2
- CADPS2 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 111/233 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs980597816, COSV57385526; called by muse, mutect2, varscan2
- CALB2 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1247948888, COSV56938258; called by muse, mutect2, varscan2
- CAPN2 | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 129/250 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99688915; called by muse, mutect2, varscan2
- CARD8 | c.337G>A p.G113R (on ENST00000651546 / NM_001184900.3; = p.G63R on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100750976; called by muse, mutect2, varscan2
- CBLL2 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 333/333 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100081486; called by muse, mutect2, varscan2
- CBLN2 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs868142587, COSV54050532; called by muse, mutect2, varscan2
- CBY2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 119/387 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60118008; called by muse, mutect2, varscan2
- CCAR2 | c.2681G>A p.R894K | Missense Mutation (SNP) | VAF 145/436 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1319622989; called by muse, mutect2, varscan2
- CCDC141 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 109/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55378738; called by muse, mutect2, varscan2
- CCDC141 | c.4166G>A p.R1389Q | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs368802405, COSV55368595; called by muse, mutect2, varscan2
- CCDC152 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 109/186 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs865979371, COSV100736676; called by muse, mutect2, varscan2
- CCDC194 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 182/481 reads (38%) | SIFT deleterious, low confidence (0.04); catalogued as rs1257505939; called by muse, mutect2, varscan2
- CCDC33 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 294/559 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as rs1273286413; called by muse, mutect2, varscan2
- CCDC54 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53758113, COSV53759291; called by muse, mutect2, varscan2
- CCDC85A | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 353/732 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1052182749, COSV68155681; called by muse, mutect2, varscan2
- CCNA1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs868177414, COSV55220741; called by muse, mutect2, varscan2
- CCNB3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1015885133, COSV52071928; called by muse, mutect2, varscan2
- CCNQ | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 269/269 reads (100%) | catalogued as COSV52344997; called by muse, mutect2, varscan2
- CCNT1 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 217/414 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs1199274008; called by muse, mutect2, varscan2
- CCR2 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 172/433 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1287456627, COSV52747932; called by muse, mutect2, varscan2
- CCT8L2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 272/545 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV63464208; called by muse, mutect2, varscan2
- CD163L1 | c.2974G>A p.G992R | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs763122935; called by muse, mutect2, varscan2
- CD163L1 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 233/521 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58023836; called by muse, mutect2, varscan2
- CD86 | c.862G>A p.E288K (on ENST00000330540 / NM_175862.5; = p.E282K on NM_006889.4) | Missense Mutation (SNP) | VAF 145/335 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV52610829; called by muse, mutect2, varscan2
- CDC37 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as rs1269283551, COSV55767893; called by muse, mutect2, varscan2
- CDCP1 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 127/270 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV56105713; called by muse, mutect2, varscan2
- CDH18 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 151/250 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2, varscan2
- CDH24 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 238/502 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.079); catalogued as rs1473827240; called by muse, mutect2, varscan2
- CDHR2 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 159/241 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs369491133; called by muse, mutect2, varscan2
- CEMIP2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as rs1564023033, COSV65490119; called by muse, mutect2, varscan2
- CFAP221 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 230/545 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs911268703; called by muse, mutect2, varscan2
- CFAP46 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 247/247 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs915496495; called by muse, mutect2, varscan2
- CFAP47 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); catalogued as COSV52885482; called by muse, mutect2, varscan2
- CFAP54 | c.5648C>T p.S1883F | Missense Mutation (SNP) | VAF 212/364 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61572231; called by muse, mutect2, varscan2
- CFAP65 | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 210/454 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs769450768, COSV58559131; called by muse, varscan2
- CHIT1 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 154/300 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55150045; called by muse, mutect2, varscan2
- CHRM2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 186/399 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as rs774760812, COSV100280682; called by muse, mutect2, varscan2
- CHST5 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 187/381 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750743459; called by muse, varscan2
- CLCA1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 167/470 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV52328887; called by muse, mutect2, varscan2
- CLCN1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58373818; called by muse, mutect2, varscan2
- CLN8 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 95/686 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs755846977, COSV58671342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLTCL1 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 277/617 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54226010; called by muse, mutect2
- CLVS2 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 123/123 reads (100%) | catalogued as COSV99253526; called by muse, mutect2, varscan2
- CLVS2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750382549, COSV51562393, COSV51567732; called by muse, mutect2, varscan2
- CNOT3 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 261/453 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1568633756; called by muse, mutect2, varscan2
- CNTN1 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 178/312 reads (57%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.886); catalogued as COSV61646038; called by muse, mutect2, varscan2
- CNTN2 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 187/384 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1050153255, COSV59348854; called by muse, mutect2, varscan2
- CNTN5 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54293685; called by muse, mutect2, varscan2
- CNTNAP5 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 190/367 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV70477966; called by muse, mutect2, varscan2
- COG3 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 139/221 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1219540725, COSV63071764; called by muse, mutect2, varscan2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, mutect2, varscan2
- COL22A1 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 142/351 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV57323756; called by muse, mutect2, varscan2
- COL4A3 | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 124/227 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM040405; called by muse, mutect2, varscan2
- COL4A3 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 132/286 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59259770; called by muse, mutect2, varscan2
- COL4A4 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 146/278 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760317280, CD155138, COSV61636551; called by muse, mutect2, varscan2
- COL5A3 | c.4181G>A p.G1394E | Missense Mutation (SNP) | VAF 255/459 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99319986; called by muse, mutect2, varscan2
- COL6A1 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 376/802 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780139552; called by muse, mutect2, varscan2
- COLEC11 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 336/732 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1159379247; called by muse, mutect2, varscan2
- COTL1 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 187/418 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV52289804; called by muse, mutect2, varscan2
- CPA2 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 231/406 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99744189; called by muse, mutect2, varscan2
- CPED1 | c.2939G>A p.G980E | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59998270; called by muse, mutect2, varscan2
- CPHXL | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.454); catalogued as rs996173484; called by muse, mutect2, varscan2
- CPNE6 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 178/382 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.061); catalogued as rs377488418; called by muse, mutect2, varscan2
- CRYGD | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 134/301 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as CM103081; called by muse, mutect2, varscan2
- CRYGS | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 174/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM091524; called by muse, mutect2, varscan2
- CSMD1 | c.2618C>T p.S873F (on ENST00000520002; = p.S872F on NM_033225.6) | Missense Mutation (SNP) | VAF 196/316 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs374785318; called by muse, mutect2, varscan2
- CSMD3 | c.6586G>A p.E2196K (on ENST00000297405 / NM_001363185.1; = p.E2092K on NM_052900.3) | Missense Mutation (SNP) | VAF 155/357 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV52103815, COSV52158512; called by muse, mutect2, varscan2
- CSNK1A1L | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.278); catalogued as rs753677756, COSV65789281; called by muse, mutect2, varscan2
- CTSE | c.938G>A p.G313E (on ENST00000360218; = p.G308E on NM_001910.4) | Missense Mutation (SNP) | VAF 173/420 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs554550981, COSV100733791; called by muse, mutect2
- CTTN | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 37/503 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs150354756; called by muse, mutect2
- CWH43 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs755347963, COSV99893684; called by muse, mutect2, varscan2
- CX3CL1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 247/496 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs771623366; called by muse, mutect2, varscan2
- CXADR | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 161/315 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs760582039, COSV53031716; called by muse, mutect2, varscan2
- CYP2B6 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV57844552; called by muse, mutect2, varscan2
- CYP4V2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV66505887; called by muse, mutect2, varscan2
- DCDC1 | c.3847G>A p.E1283K (on ENST00000597505 / NM_001367979.1; = p.E390K on NM_020869.3) | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100338224; called by muse, mutect2, varscan2
- DCLK1 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 109/170 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1438658565; called by muse, mutect2, varscan2
- DDX19A | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 223/484 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1451860677, COSV100156250; called by muse, mutect2, varscan2
- DIS3L2 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 179/378 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs901797759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLL1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 400/402 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs1423089390; called by muse, mutect2, varscan2
- DMC1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 145/315 reads (46%) | catalogued as rs1300163639, COSV53258029; called by muse, mutect2, varscan2
- DMRT1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV66522051; called by muse, mutect2, varscan2
- DMRT2 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as COSV52403673; called by muse, mutect2, varscan2
- DNA2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 191/192 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190205288; called by muse, mutect2, varscan2
- DNAH14 | c.3031C>T p.P1011S (on ENST00000445597; = p.P1185S on NM_001367479.1) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1260575449; called by muse, mutect2, varscan2
- DNAH14 | c.3104C>T p.S1035L (on ENST00000445597; = p.S1419L on NM_001367479.1) | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV100144730; called by muse, mutect2, varscan2
- DNAH3 | c.8188G>A p.G2730R | Missense Mutation (SNP) | VAF 285/596 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs779186366; called by muse, mutect2, varscan2
- DNAH3 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 148/304 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs777984798, COSV54506633; called by muse, mutect2, varscan2
- DNAH5 | c.11143G>A p.D3715N | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54213955; called by muse, mutect2, varscan2
- DNAH5 | c.7601C>T p.A2534V | Missense Mutation (SNP) | VAF 190/288 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773382166; called by muse, mutect2, varscan2
- DNAH5 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54218169; called by muse, mutect2, varscan2
- DNAH5 | c.798G>A p.Q266= | Splice Region (SNP) | VAF 89/134 reads (66%) | catalogued as COSV54247405; called by muse, mutect2, varscan2
- DNMT3B | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 46/513 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV52416663; called by muse, mutect2
- DPM1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1228034716; called by muse, mutect2, varscan2
- DSCAM | c.4135C>T p.P1379S | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68026494; called by muse, mutect2, varscan2
- DSCAML1 | c.5039G>A p.R1680Q (on ENST00000321322; = p.R1620Q on NM_020693.4) | Missense Mutation (SNP) | VAF 168/312 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs566658468; called by muse, mutect2, varscan2
- E2F7 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 106/405 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59738138; called by muse, mutect2, varscan2
- EDIL3 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 106/139 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV56916147; called by muse, mutect2, varscan2
- EGFR | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 171/387 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV51815916; called by muse, mutect2, varscan2
- ELAPOR1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 187/333 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs147483565; called by muse, mutect2, varscan2
- ELN | c.2030C>T p.A677V (on ENST00000320399 / NM_001278939.1; = p.A644V on NM_000501.4) | Missense Mutation (SNP) | VAF 139/359 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1554686787; called by muse, mutect2, varscan2
- ELOVL4 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 95/95 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV100876420; called by muse, mutect2, varscan2
- EPB41L4B | c.2223G>A p.K741= | Splice Region (SNP) | VAF 120/120 reads (100%) | catalogued as COSV100775854; called by muse, mutect2, varscan2
- EPHA3 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60733710; called by mutect2, varscan2
- EPHA3 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 145/317 reads (46%) | catalogued as rs774448099, COSV60696980, COSV60729273; called by muse, mutect2, varscan2
- EPOP | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 492/990 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs939617129; called by muse, mutect2, varscan2
- ERAL1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1234499601; called by muse, mutect2, varscan2
- ERBB3 | c.3401C>T p.S1134F | Missense Mutation (SNP) | VAF 304/586 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1334721954, COSV57258200; called by muse, mutect2
- ERCC6 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs774463252; called by muse, mutect2, varscan2
- ERG | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 225/502 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV55731409; called by muse, mutect2, varscan2
- FAM20C | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 187/1260 reads (15%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs1239831432, COSV58232514; called by muse, mutect2, varscan2
- FAM47A | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.417); catalogued as rs753213065; called by muse, mutect2, varscan2
- FANCD2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758628578; called by muse, mutect2, varscan2
- FARP2 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761808991, COSV50886042; called by muse, mutect2, varscan2
- FAT3 | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 127/280 reads (45%) | catalogued as COSV53087104, COSV53153984, COSV99961331; called by muse, mutect2, varscan2
- FBN3 | c.3019G>A p.G1007S | Missense Mutation (SNP) | VAF 151/357 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs771402425; called by muse, mutect2, varscan2
- FBXO28 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 359/656 reads (55%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1366228531; called by muse, mutect2, varscan2
- FCRL1 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 90/169 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV63824711; called by muse, mutect2, varscan2
- FCRL1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 144/290 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100839700; called by muse, mutect2, varscan2
- FCRL3 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63840285; called by muse, mutect2, varscan2
- FEM1A | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 245/519 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54163556; called by muse, mutect2, varscan2
- FFAR2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 204/381 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.086); catalogued as COSV55832014; called by muse, mutect2, varscan2
- FKBP4 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 273/473 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV50010022; called by muse, mutect2, varscan2
- FLG | c.12137C>T p.S4046L | Missense Mutation (SNP) | VAF 173/303 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs752715330, COSV64241792; called by muse, mutect2, varscan2
- FMN2 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 281/537 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as rs1322566748, COSV60444520; called by muse, mutect2, varscan2
- FPR3 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 199/400 reads (50%) | catalogued as rs1199889444; called by muse, mutect2, varscan2
- FREM1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 189/191 reads (99%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV66521623; called by muse, mutect2, varscan2
- FRRS1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV54921391; called by muse, mutect2, varscan2
- FRY | c.7259C>T p.S2420L | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1458250699; called by muse, mutect2, varscan2
- GABRE | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100944205, COSV64819519; called by muse, mutect2, varscan2
- GABRG1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV99778742; called by muse, mutect2, varscan2
- GALNT13 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV67221076, COSV67234015; called by muse, mutect2, varscan2
- GALNT17 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 129/337 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV61164483; called by muse, mutect2, varscan2
- GALNT6 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 318/620 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779892656; called by muse, varscan2
- GAS2L2 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 248/521 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs140261341; called by muse, mutect2, varscan2
- GASK1A | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 228/410 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); catalogued as rs1378628533; called by muse, mutect2, varscan2
- GBP6 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100969436, COSV100969734; called by muse, mutect2, varscan2
- GGT1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 191/615 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs764046660; called by muse, varscan2
- GIMAP7 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57959691; called by muse, mutect2, varscan2
- GLI3 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 140/421 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV67894917; called by muse, mutect2, varscan2
- GLRB | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 139/305 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1053763362, COSV100029715; called by muse, mutect2, varscan2
- GLT6D1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 207/207 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV65627650; called by muse, mutect2, varscan2
- GLUD2 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 279/282 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100047193; called by muse, mutect2, varscan2
- GMEB1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53793859; called by muse, mutect2, varscan2
- GOLGA6L7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs3894983; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 105/537 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPC5 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs199697192, COSV65573069; called by muse, mutect2, varscan2
- GPR155 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1040797683; called by muse, mutect2, varscan2
- GPRIN1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 142/256 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV56138616; called by muse, mutect2, varscan2
- GRIA1 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868690124, COSV53598231; called by muse, mutect2, varscan2
- GRIN2A | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58026843; called by muse, mutect2, varscan2
- GRM8 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 218/403 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58833155; called by muse, mutect2, varscan2
- GTPBP4 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs866138946, COSV62551604; called by muse, mutect2, varscan2
- GTPBP4 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs762424442; called by muse, mutect2, varscan2
- HAL | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 240/441 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV54117031; called by muse, mutect2, varscan2
- HCFC1 | c.3920C>T p.T1307I | Missense Mutation (SNP) | VAF 456/456 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs1200447937; called by muse, mutect2, varscan2
- HCLS1 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 198/383 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57521970; called by muse, mutect2, varscan2
- HECW1 | c.3047C>T p.T1016I | Missense Mutation (SNP) | VAF 190/358 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs1196857055; called by muse, mutect2, varscan2
- HECW1 | c.4690A>C p.K1564Q | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1279263202; called by muse, mutect2, varscan2
- HEPH | c.772G>A p.E258K (on ENST00000343002; = p.E312K on NM_138737.5) | Missense Mutation (SNP) | VAF 230/231 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs1207748479, COSV100294897; called by muse, mutect2, varscan2
- HGFAC | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 165/396 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1372078144; called by muse, mutect2, varscan2
- HMG20A | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs558556183, COSV100287638, COSV60313254; called by muse, mutect2, varscan2
- HMGCS2 | c.1422G>A p.V474= | Splice Region (SNP) | VAF 119/200 reads (60%) | catalogued as COSV65567731; called by muse, mutect2, varscan2
- HSD3B7 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413301395, COSV52682550; called by muse, mutect2, varscan2
- HSPA1L | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 268/602 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV65149096; called by muse, mutect2
- HYDIN | c.9254C>T p.S3085F | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.242); catalogued as COSV59256947; called by muse, mutect2, varscan2
- IARS2 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.048); catalogued as rs1558132313; called by muse, mutect2, varscan2
- IDO1 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 217/344 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs773380478, COSV53716665; called by muse, mutect2, varscan2
- IGSF5 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 143/342 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1424253803; called by muse, mutect2
- IGSF9 | c.2345C>T p.S782F (on ENST00000368094 / NM_001135050.2; = p.S766F on NM_020789.4) | Missense Mutation (SNP) | VAF 150/297 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100231020; called by muse, mutect2, varscan2
- IL36B | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 110/228 reads (48%) | catalogued as COSV52089406, COSV99382640; called by muse, mutect2, varscan2
- INSM1 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 553/1024 reads (54%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.55); catalogued as rs1183199988; called by muse, mutect2, varscan2
- ITGA1 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1258296706; called by muse, mutect2, varscan2
- ITGA2 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56864719; called by muse, mutect2, varscan2
- ITGB8 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.203); catalogued as rs1273987083, COSV56006640; called by muse, mutect2, varscan2
- JAKMIP2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 104/169 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54596724; called by muse, mutect2, varscan2
- JPH4 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 338/723 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767937104, COSV58115616; called by muse, mutect2, varscan2
- KANK4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 246/405 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.134); catalogued as rs868518757, COSV62986804; called by muse, mutect2, varscan2
- KCNH5 | c.2423G>A p.G808E | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.055); catalogued as COSV59753891; called by muse, mutect2, varscan2
- KCNN1 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 266/665 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs200591698; called by muse, mutect2, varscan2
- KCNQ3 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 178/345 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1005759975, COSV66464839; called by muse, mutect2, varscan2
- KCNU1 | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV67754273; called by muse, mutect2, varscan2
- KCTD16 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs776301270, COSV72580946; called by muse, mutect2, varscan2
- KIF13B | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 147/249 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265020735; called by muse, mutect2, varscan2
- KIF5C | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 368/776 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1017774533, COSV68479604; called by muse, mutect2, varscan2
- KLHL40 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 192/466 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV55133680; called by muse, mutect2, varscan2
- KLK3 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 128/247 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV58103126; called by muse, mutect2, varscan2
- KLRG2 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61801928; called by muse, mutect2, varscan2
- KMT2D | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 269/487 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV56412881; called by muse, mutect2, varscan2
- KRT25 | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 171/360 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV56443781; called by muse, mutect2, varscan2
- KRT36 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 260/570 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs1467116745; called by muse, mutect2, varscan2
- KRT86 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 224/544 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53291912; called by muse, mutect2, varscan2
- KRTAP19-2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 250/486 reads (51%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.851); catalogued as rs141067359; called by muse, mutect2, varscan2
- KSR2 | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 168/393 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as rs770369161, COSV100196989; called by muse, mutect2, varscan2
- L3MBTL1 | c.2351C>T p.T784I (on ENST00000418998 / NM_001377303.1; = p.T694I on NM_015478.7) | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV64228238; called by muse, mutect2, varscan2
- LAMA1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 216/339 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057279; called by muse, mutect2, varscan2
- LAMB3 | c.2493G>A p.M831I | Missense Mutation (SNP) | VAF 225/465 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1328873531; called by muse, mutect2, varscan2
- LCT | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs768179301; called by muse, varscan2
- LEPR | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100756471; called by muse, mutect2, varscan2
- LGI2 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 226/395 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV66122359; called by muse, mutect2, varscan2
- LGSN | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs868211176, COSV65728092; called by muse, mutect2, varscan2
- LIG1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs372022915; called by muse, mutect2, varscan2
- LILRA1 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 322/748 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as rs772540119; called by muse, mutect2, varscan2
- LRFN2 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 144/329 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV57825416; called by muse, mutect2, varscan2
- LRFN5 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 164/368 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs1051039315, COSV53243316, COSV53273551; called by muse, mutect2, varscan2
- LRIG1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 165/440 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs1054086085, COSV56249478; called by muse, mutect2, varscan2
- LRP2 | c.9124G>A p.G3042R | Missense Mutation (SNP) | VAF 286/573 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs376039022; called by muse, mutect2, varscan2
- LRP2 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 171/350 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs747942310, COSV55539979; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3556C>T p.R1186* | Nonsense Mutation (SNP) | VAF 364/751 reads (48%) | catalogued as rs1346280528, COSV51599199; called by muse, mutect2, varscan2
- MARK4 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 125/298 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1013318216, COSV53462070; called by muse, mutect2, varscan2
- MASP1 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 238/519 reads (46%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV51457577; called by muse, mutect2, varscan2
- MAST3 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 161/428 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53225726; called by muse, mutect2
- MBL2 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 151/154 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV64758165; called by muse, mutect2, varscan2
- MCF2 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); catalogued as rs764011158, COSV58477096; called by muse, mutect2, varscan2
- MCM6 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51470630; called by muse, mutect2, varscan2
- MED17 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 108/192 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs568876133, COSV52599249; called by muse, mutect2, varscan2
- MEGF6 | c.3127C>T p.R1043W | Missense Mutation (SNP) | VAF 285/607 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs752133585; called by muse, mutect2, varscan2
- MEGF8 | c.8491C>T p.R2831W (on ENST00000251268 / NM_001271938.2; = p.R2764W on NM_001410.3) | Missense Mutation (SNP) | VAF 294/565 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs763261685, COSV52106164; called by muse, mutect2, varscan2
- MEIKIN | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 137/193 reads (71%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs59867664; called by muse, mutect2, varscan2
- MEX3D | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 364/886 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs1317566677; called by muse, mutect2, varscan2
- MGA | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54955933; called by muse, mutect2, varscan2
- MGAM | c.2068G>A p.G690S | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as rs1554465807; called by muse, mutect2, varscan2
- MIPEP | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 104/185 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV66300340; called by muse, mutect2, varscan2
- MKX | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 104/104 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs138096382, COSV65392192; called by muse, mutect2, varscan2
- MLXIP | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 459/826 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as rs757642194; called by muse, mutect2, varscan2
- MMP17 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 265/519 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372874449; called by muse, mutect2, varscan2
- MMP17 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 261/515 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750130696; called by muse, mutect2, varscan2
- MMP3 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV55405735; called by muse, mutect2, varscan2
- MMP9 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 270/632 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201191171, COSV63433971; called by muse, mutect2, varscan2
- MORC1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV99225584; called by muse, mutect2, varscan2
- MPP7 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs868690750, COSV61730420; called by muse, mutect2, varscan2
- MROH2A | c.4068G>A p.M1356I | Missense Mutation (SNP) | VAF 234/528 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1345638984; called by muse, mutect2, varscan2
- MROH2B | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 180/253 reads (71%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs771053680, COSV68183965; called by muse, mutect2, varscan2
- MROH5 | c.3482G>A p.R1161Q | Missense Mutation (SNP) | VAF 343/758 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.178); catalogued as rs758897313, COSV61472445; called by muse, mutect2, varscan2
- MS4A14 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55737750; called by muse, mutect2, varscan2
- MSH3 | c.3303-1G>A p.X1101_splice | Splice Site (SNP) | VAF 81/102 reads (79%) | catalogued as rs779621335, COSV54149805; called by muse, mutect2, varscan2
- MTSS2 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 374/795 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1257112176, COSV55381210; called by muse, mutect2, varscan2
- MTTP | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.773); catalogued as rs777178178; called by muse, mutect2
- MUC12 | c.15967G>A p.G5323R (on ENST00000379442; = p.G5180R on NM_001164462.1) | Missense Mutation (SNP) | VAF 201/392 reads (51%) | SIFT deleterious (0); catalogued as rs1467584342; called by muse, mutect2, varscan2
- MUC16 | c.37595C>T p.S12532F | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV67489576; called by muse, mutect2, varscan2
- MUC16 | c.37517C>T p.T12506I | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as rs1179610009; called by muse, mutect2, varscan2
- MUC16 | c.36167G>A p.G12056E | Missense Mutation (SNP) | VAF 154/286 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs1268095405; called by muse, mutect2, varscan2
- MUC16 | c.30050A>T p.K10017I | Missense Mutation (SNP) | VAF 142/267 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as rs1449882263; called by muse, mutect2, varscan2
- MUC16 | c.28210C>T p.P9404S | Missense Mutation (SNP) | VAF 198/458 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.112); catalogued as COSV67454389; called by muse, mutect2, varscan2
- MUC16 | c.17552C>T p.P5851L | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV101200752, COSV67494343; called by muse, varscan2
- MUC20 | c.1512C>G p.S504R | Missense Mutation (SNP) | VAF 440/1550 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV100290859; called by muse, mutect2
- MUC22 | c.2614G>A p.G872S | Missense Mutation (SNP) | VAF 414/878 reads (47%) | SIFT tolerated (0.74); catalogued as rs533911260; called by muse, mutect2, varscan2
- MYBPC1 | c.2140C>T p.P714S (on ENST00000550270 / NM_206820.2; = p.P739S on NM_002465.4) | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62257795; called by muse, mutect2, varscan2
- MYH3 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs770850703; called by muse, mutect2, varscan2
- MYO18B | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 306/585 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746828963, COSV100122452; called by muse, mutect2, varscan2
- MYO18B | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 195/372 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as rs747649794; called by muse, mutect2, varscan2
- MYO9A | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 162/372 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1385098734; called by muse, mutect2, varscan2
- MYOM2 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1489890751, COSV100036363; called by muse, mutect2, varscan2
- NAA11 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 194/390 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV54513859; called by muse, varscan2
- NAIP | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 47/168 reads (28%) | catalogued as COSV52002764; called by muse, mutect2, varscan2
- NBEAL2 | c.4675C>T p.R1559C | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1167971882, COSV52756317; called by muse, mutect2, varscan2
- NCF2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV62316384, COSV62316714; called by muse, mutect2, varscan2
- NCKAP5 | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 251/506 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772271616; called by muse, mutect2, varscan2
- NCKAP5 | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 146/338 reads (43%) | catalogued as COSV58458770; called by muse, mutect2, varscan2
- NEBL | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65803562; called by muse, mutect2, varscan2
- NEK11 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 177/362 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs753408315; called by muse, mutect2, varscan2
- NEXMIF | c.4406G>A p.R1469Q | Missense Mutation (SNP) | VAF 267/268 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs151004644, COSV50088606, COSV99280286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEXMIF | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 308/308 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50021777; called by muse, mutect2, varscan2
- NGF | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 174/422 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772557857, COSV101049373, COSV65686846; called by muse, mutect2, varscan2
- NIF3L1 | c.377C>T p.P126L (on ENST00000409020 / NM_001369444.1; = p.P99L on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 200/423 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1289394079; called by muse, mutect2, varscan2
- NLRP13 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 196/460 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as rs756785974, COSV100738135, COSV61621910; called by muse, mutect2, varscan2
- NPC1L1 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 238/430 reads (55%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.962); catalogued as rs1020364078, COSV56924564, COSV99207622; called by muse, mutect2, varscan2
- NPIPA2 | c.983C>T p.P328L (on ENST00000529166; = p.P309L on NM_001277324.1) | Missense Mutation (SNP) | VAF 193/419 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs916551240; called by mutect2, varscan2
- NRK | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as rs888770792, COSV54604905; called by muse, mutect2, varscan2
- NRXN1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 175/381 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as COSV58491483; called by muse, mutect2, varscan2
- NUP210L | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 155/288 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs1156326453; called by muse, mutect2, varscan2
- NUTM1 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 184/184 reads (100%) | catalogued as COSV61548337, COSV99068029; called by muse, mutect2, varscan2
- NUTM2B | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.219); catalogued as rs1473690635; called by muse, mutect2, varscan2
- OBSCN | c.5141T>C p.L1714P | Missense Mutation (SNP) | VAF 175/302 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99486498; called by muse, mutect2, varscan2
- OBSCN | c.18943G>A p.E6315K | Missense Mutation (SNP) | VAF 175/346 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs1229798322; called by muse, mutect2, varscan2
- OLFM4 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 151/261 reads (58%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs1300049047; called by muse, mutect2, varscan2
- ONECUT2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 298/403 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72153032; called by muse, varscan2
- OR10C1 | c.784C>T p.R262C (on ENST00000622521; = p.R260C on NM_013941.3) | Missense Mutation (SNP) | VAF 397/829 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1358295170, COSV65822163, COSV65823505; called by muse, mutect2
- OR10K2 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 197/361 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV59221871; called by muse, mutect2, varscan2
- OR11H4 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.129); catalogued as rs200685446, COSV59560667; called by muse, mutect2, varscan2
- OR13D1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs78179625; called by muse, mutect2, varscan2
- OR14C36 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 145/369 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV58602821; called by muse, mutect2, varscan2
- OR1S2 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 160/417 reads (38%) | catalogued as rs377033485, COSV56921388; called by muse, mutect2, varscan2
- OR2M3 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs769867138, COSV71759339; called by muse, mutect2, varscan2
- OR2T1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 267/655 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822237, COSV63541456; called by muse, mutect2, varscan2
- OR2W1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1457469077; called by muse, mutect2, varscan2
- OR2Z1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 213/428 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV60691737; called by muse, mutect2, varscan2
- OR4C15 | c.998C>A p.P333H (on ENST00000314644; = p.P279H on NM_001001920.2) | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs550535681, COSV58954607; called by muse, mutect2, varscan2
- OR4C6 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58604443; called by muse, mutect2, varscan2
- OR4K1 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 158/314 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs780258802, COSV53459128, COSV53461758, COSV53462479; called by muse, mutect2, varscan2
- OR4N2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs371446325, COSV60056053; called by muse, mutect2, varscan2
- OR52H1 | c.793C>T p.R265C (on ENST00000322653; = p.R271C on NM_001005289.1) | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs776491274, COSV59505819; called by muse, varscan2
- OR52H1 | c.277G>A p.E93K (on ENST00000322653; = p.E99K on NM_001005289.1) | Missense Mutation (SNP) | VAF 133/135 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1212940600, COSV59505036; called by muse, mutect2, varscan2
- OR5M3 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 184/362 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs777652801; called by muse, mutect2, varscan2
- OR6A2 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 211/212 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs201451646, COSV60264583, COSV60264692; called by muse, mutect2, varscan2
- OR6C3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 71/179 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.38); catalogued as rs1369757690; called by muse, mutect2, varscan2
- OR6C6 | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1183165582; called by muse, mutect2, varscan2
- OR6C70 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 66/124 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV100524387, COSV59245434; called by muse, mutect2, varscan2
- OR8H3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 184/356 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs746567502, COSV100539087, COSV57908363; called by muse, varscan2
- OR8S1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 224/474 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59599496, COSV59599766; called by muse, mutect2, varscan2
- OSBPL11 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 169/357 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs1467502370; called by muse, mutect2, varscan2
- OSBPL6 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770182984, COSV51928884; called by muse, mutect2, varscan2
- OTOG | c.3016G>A p.G1006R | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165447134, COSV61133093; called by muse, mutect2, varscan2
- P3H2 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 183/375 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as COSV60028527; called by muse, mutect2, varscan2
- P3H2 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 125/240 reads (52%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs767531569, COSV60018370; called by muse, mutect2, varscan2
- PADI2 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 167/369 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100971044; called by muse, mutect2, varscan2
- PAFAH1B1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as CM073253, COSV68210606; called by muse, mutect2, varscan2
- PAPLN | c.1391C>T p.S464F (on ENST00000554301; = p.S437F on NM_173462.4) | Missense Mutation (SNP) | VAF 316/648 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV99389252; called by muse, mutect2, varscan2
- PAX8 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 237/534 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1301648607; called by muse, mutect2, varscan2
- PBRM1 | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 87/228 reads (38%) | catalogued as COSV56280699, COSV56312187; called by muse, mutect2, varscan2
- PCDH15 | c.3692G>A p.G1231E | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV57350301; called by muse, mutect2, varscan2
- PCDH15 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs766924319; called by muse, mutect2, varscan2
- PCDH18 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 211/495 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs1040505669, COSV61267860; called by muse, mutect2, varscan2
- PCDHA3 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs35124371, COSV65364303; called by muse, mutect2, varscan2
- PCDHB14 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 211/344 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV53386204; called by muse, mutect2, varscan2
- PCDHB7 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs782805831, COSV50809413; called by muse, mutect2, varscan2
- PCDHB8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.113); catalogued as rs782572409; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 163/250 reads (65%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGA2 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 236/335 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as rs1452914479; called by muse, mutect2, varscan2
- PCDHGA8 | c.938del p.S313Yfs*28 | Frame Shift Del (DEL) | VAF 44/180 reads (24%) | catalogued as COSV53953049; called by mutect2, pindel, varscan2
- PCDHGA9 | c.1208G>T p.R403I | Missense Mutation (SNP) | VAF 133/193 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV54038577; called by muse, mutect2, varscan2
- PCLO | c.11198C>T p.S3733F | Missense Mutation (SNP) | VAF 218/382 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV61622891, COSV61668169; called by muse, mutect2, varscan2
- PDE1A | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs757725272, COSV59542273; called by muse, mutect2, varscan2
- PDE1B | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs112699956, COSV54496508; called by muse, mutect2, varscan2
- PDE1C | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 177/308 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as rs1018039717, COSV58511496; called by muse, mutect2, varscan2
- PDE3A | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 291/293 reads (99%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1362263603; called by muse, mutect2, varscan2
- PDE4DIP | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 191/377 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs1553604534; called by muse, mutect2, varscan2
- PDE6B | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 190/484 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as rs1299193084; called by muse, mutect2, varscan2
- PDGFC | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 195/382 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285168954, COSV56847587; called by muse, mutect2, varscan2
- PELP1 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52586699; called by muse, mutect2, varscan2
- PICK1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 308/722 reads (43%) | catalogued as rs373829961; called by muse, mutect2, varscan2
- PIEZO2 | c.6089G>A p.R2030Q | Missense Mutation (SNP) | VAF 195/253 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs372801656; called by muse, mutect2, varscan2
- PIK3C3 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 221/274 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56278822; called by muse, mutect2, varscan2
- PIK3R4 | c.2183T>A p.I728K | Missense Mutation (SNP) | VAF 109/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100768405; called by muse, mutect2, varscan2
- PKHD1L1 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs866082318, COSV101006541; called by muse, mutect2, varscan2
- PKIA | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 155/302 reads (51%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.476); catalogued as COSV100775179; called by muse, mutect2, varscan2
- PLG | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99805130; called by muse, mutect2, varscan2
- PLVAP | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 235/551 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV53087721; called by muse, mutect2, varscan2
- PLXNB1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 295/673 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1232940706; called by muse, mutect2, varscan2
- PMS2 | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 111/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56219399, COSV56221623; called by muse, mutect2, varscan2
- POC5 | c.88G>A p.E30K (on ENST00000428202 / NM_001099271.2; = p.E5K on NM_152408.2) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65974072; called by muse, mutect2, varscan2
- POLRMT | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 225/517 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568170660; called by muse, mutect2, varscan2
- POM121L12 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 205/405 reads (51%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.038); catalogued as rs1481598999; called by muse, mutect2, varscan2
- POMC | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 426/873 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs924300699, COSV53034440; called by muse, mutect2
- POTEH | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 356/1926 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); catalogued as rs1381046225, COSV58879471; called by muse, varscan2
- POTEJ | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs1232179286; called by muse, mutect2, varscan2
- PPP1R37 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 336/664 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs1388797421; called by muse, mutect2, varscan2
- PPP4R3B | c.1954A>T p.T652S (on ENST00000616407 / NM_001122964.3; = p.T567S on NM_020463.4) | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1011345443, COSV55401468; called by muse, mutect2, varscan2
- PPP4R3C | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs913207652; called by muse, mutect2, varscan2
- PRAMEF12 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as rs759490121; called by muse, mutect2, varscan2
- PRAMEF12 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 227/467 reads (49%) | catalogued as COSV63216691; called by muse, mutect2, varscan2
- PRG4 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 307/780 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs765948419; called by muse, mutect2, varscan2
- PRICKLE1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 109/195 reads (56%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.947); catalogued as COSV58208230; called by muse, mutect2, varscan2
- PRKAR1A | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 394/394 reads (100%) | catalogued as rs867753055, CM043329; called by muse, mutect2, varscan2
- PRKCG | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 150/368 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.208); catalogued as rs777151978; called by muse, mutect2, varscan2
- PROX1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 195/346 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.185); catalogued as rs778243658; called by muse, mutect2, varscan2
- PROZ | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 198/295 reads (67%) | catalogued as rs1415485962, COSV61439593; called by muse, mutect2, varscan2
- PRRX1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770288919, COSV53410645; called by muse, mutect2, varscan2
- PRRX2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 369/370 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs144448846; called by muse, mutect2, varscan2
- PRSS37 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs766210306, COSV63339047; called by muse, mutect2, varscan2
- PRSS51 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 241/397 reads (61%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.951); catalogued as rs916141900; called by muse, mutect2, varscan2
- PRTG | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1372142654; called by muse, mutect2, varscan2
- PSG11 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV100105587; called by muse, mutect2, varscan2
- PSTPIP1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 149/273 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs934905433; called by muse, mutect2, varscan2
- PSTPIP1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 188/372 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs569030059; called by muse, mutect2, varscan2
- PTPRB | c.4670G>A p.G1557E | Missense Mutation (SNP) | VAF 211/376 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758187856; called by muse, mutect2, varscan2
- PTPRC | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100722687; called by muse, mutect2, varscan2
- PTPRD | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61930393, COSV61932762; called by muse, mutect2, varscan2
- PXDNL | c.3634G>A p.G1212R | Missense Mutation (SNP) | VAF 171/407 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62485695; called by muse, mutect2, varscan2
- RABL6 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 356/360 reads (99%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1229693254; called by muse, mutect2
- RBM25 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV56200269; called by muse, mutect2, varscan2
- RBM47 | c.1777T>A p.Y593N (on ENST00000295971 / NM_001098634.2; = p.Y524N on NM_019027.4) | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs1373402204; called by mutect2, varscan2
- RELN | c.8117C>T p.S2706L | Missense Mutation (SNP) | VAF 107/187 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs754633660, COSV58999421; called by muse, mutect2, varscan2
- REXO1 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 268/461 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs752333222; called by muse, varscan2
- RFX3 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56524912; called by muse, mutect2, varscan2
- RHCE | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 114/642 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV53803305; called by muse, mutect2, varscan2
- RIMBP2 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 192/381 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1328831484, COSV55469201; called by muse, mutect2, varscan2
- RIMBP2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 204/470 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752540968; called by muse, mutect2, varscan2
- RND3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55725589; called by muse, mutect2, varscan2
- RNF157 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 417/417 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs1344005107, COSV53944348; called by muse, mutect2, varscan2
- RNF17 | c.3772A>C p.R1258= | Splice Region (SNP) | VAF 72/154 reads (47%) | catalogued as rs1426472812; called by muse, mutect2, varscan2
- RNF186 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 291/631 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs745415535; called by muse, mutect2, varscan2
- RNF2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 120/305 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as rs111732754; called by muse, mutect2, varscan2
- RNF213 | c.13618C>T p.R4540W | Missense Mutation (SNP) | VAF 428/429 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs530930845; called by muse, mutect2, varscan2
- RNF227 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 366/366 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766358919; called by muse, mutect2, varscan2
- ROBO3 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 171/426 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV67302088; called by muse, mutect2, varscan2
- RP1 | c.2241T>G p.S747R | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV55122433; called by muse, mutect2, varscan2
- RP1 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 161/323 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1168430795; called by muse, mutect2, varscan2
- RP1L1 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 194/554 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs748858444, COSV101223393; called by muse, mutect2, varscan2
- RSPH3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 317/317 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs546435437, COSV51922159; called by muse, mutect2, varscan2
- RTL1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 241/484 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV66016822; called by muse, mutect2, varscan2
- RUNX1T1 | c.1484G>C p.R495P (on ENST00000265814 / NM_001198628.1; = p.R468P on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 240/507 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV56152742, COSV56166983; called by muse, mutect2, varscan2
- RUSC1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 216/408 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.432); catalogued as COSV52738777; called by muse, mutect2, varscan2
- RXFP1 | c.900G>A p.L300= | Splice Region (SNP) | VAF 75/173 reads (43%) | catalogued as COSV57045948; called by muse, mutect2, varscan2
- RYR1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.549); catalogued as COSV100614943; called by muse, mutect2, varscan2
- RYR1 | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 215/365 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62093581; called by muse, mutect2, varscan2
- RYR1 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 317/565 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.615); catalogued as rs372652716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.9671C>T p.P3224L | Missense Mutation (SNP) | VAF 145/349 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as rs373626870; called by muse, mutect2, varscan2
- S100A12 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 227/445 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs1472253923, COSV64198988; called by muse, mutect2, varscan2
- S100A7 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 180/323 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs138333032, COSV64193834; called by muse, mutect2, varscan2
- SALL1 | c.3356C>T p.S1119F | Missense Mutation (SNP) | VAF 254/553 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs267604570; called by muse, mutect2, varscan2
- SCAMP1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 73/102 reads (72%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs750834214; called by muse, mutect2, varscan2
- SCAMP1 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 73/102 reads (72%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as COSV100210618; called by muse, mutect2, varscan2
- SCN3A | c.5801G>A p.G1934E | Missense Mutation (SNP) | VAF 139/279 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs776798468; called by muse, mutect2, varscan2
- SCN7A | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV69270997; called by muse, mutect2, varscan2
- SCN8A | c.5834C>T p.P1945L | Missense Mutation (SNP) | VAF 260/483 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766045454, COSV100634482; called by muse, mutect2, varscan2
- SELENOP | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267600641, COSV62792715; called by muse, mutect2, varscan2
- SEMA3G | c.2086G>A p.G696R | Missense Mutation (SNP) | VAF 235/469 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs768949976; called by muse, mutect2, varscan2
- SEMA5B | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 118/224 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52092447; called by muse, mutect2, varscan2
- SEMA6C | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 140/256 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412160295; called by muse, mutect2, varscan2
- SEMG1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV54872665; called by muse, mutect2, varscan2
- SEMG2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV65647781, COSV65648049; called by muse, mutect2, varscan2
- SERPINA5 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 235/497 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs768086313; called by muse, mutect2, varscan2
- SERPINB2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 205/298 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55092265; called by muse, mutect2, varscan2
- SERPING1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 175/378 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV53541497; called by muse, mutect2, varscan2
- SF3A1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 137/305 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99305479; called by muse, mutect2, varscan2
- SHOX | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 560/668 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1483008877; called by muse, mutect2, varscan2
- SI | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs914960775, COSV52265279; called by muse, mutect2, varscan2
- SIMC1 | c.494C>T p.S165F (on ENST00000443967 / NM_001308196.1; = p.S184F on NM_001308195.2) | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as COSV57900434; called by muse, mutect2, varscan2
- SIPA1L1 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 126/316 reads (40%) | catalogued as COSV100665221; called by muse, mutect2, varscan2
- SIRPG | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 158/424 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as rs772163644; called by muse, mutect2, varscan2
- SIRPG | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs752934849; called by muse, mutect2
- SLC12A8 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 225/469 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1208821444; called by muse, mutect2, varscan2
- SLC1A4 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 194/432 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99308995; called by muse, mutect2, varscan2
- SLC1A6 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 229/492 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1234633468; called by muse, mutect2, varscan2
- SLC26A9 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 115/211 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61602083; called by muse, mutect2, varscan2
- SLC28A1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 188/422 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV54479863; called by muse, mutect2, varscan2
- SLC38A1 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 164/286 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs145483756, COSV67064177; called by muse, mutect2, varscan2
- SLC38A1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV67062947, COSV67063639; called by muse, varscan2
- SLC4A10 | c.1300C>T p.P434S (on ENST00000446997 / NM_001354461.2; = p.P404S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/315 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55795783, COSV55796673; called by muse, mutect2, varscan2
- SLC5A8 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 183/387 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs908258766; called by muse, mutect2, varscan2
- SLITRK1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 192/301 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65675639; called by muse, mutect2, varscan2
- SMARCC1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 33/360 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.979); catalogued as rs751471726, COSV99593590; called by muse, mutect2
- SMG7 | c.1033T>A p.C345S | Missense Mutation (SNP) | VAF 126/247 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.158); catalogued as COSV61632543; called by muse, mutect2, varscan2
- SMIM23 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1338436343; called by muse, mutect2, varscan2
- SNCAIP | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54404822; called by muse, mutect2, varscan2
- SND1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 194/369 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs148173300; called by muse, mutect2, varscan2
- SNTG1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52428271; called by muse, mutect2, varscan2
- SP140L | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 164/305 reads (54%) | catalogued as rs373078245, COSV54741506, COSV54743817; called by muse, mutect2, varscan2
- SPAG1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1254116266, COSV99308419; called by muse, mutect2, varscan2
- SPDYA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs771698422, COSV61856457; called by muse, mutect2, varscan2
- SPDYC | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 270/641 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1327641593; called by muse, mutect2, varscan2
- SPEG | c.8425C>T p.P2809S | Missense Mutation (SNP) | VAF 280/565 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1479880971; called by muse, mutect2, varscan2
- SPINK5 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 180/261 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV56252052; called by muse, mutect2, varscan2
- SPN | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 255/575 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64071078; called by muse, mutect2, varscan2
- SPTA1 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 113/204 reads (55%) | catalogued as COSV63749571; called by muse, mutect2, varscan2
- SPTBN5 | c.6491G>A p.W2164* | Nonsense Mutation (SNP) | VAF 131/132 reads (99%) | catalogued as rs1252856748, COSV58020757; called by muse, mutect2, varscan2
- SSX1 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1182043071; called by muse, mutect2, varscan2
- ST8SIA3 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 362/472 reads (77%) | PolyPhen benign (0.072); catalogued as rs1439709150, COSV60653476; called by muse, mutect2, varscan2
- ST8SIA5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 103/522 reads (20%) | PolyPhen benign (0.015); catalogued as rs772209308, COSV59330330; called by muse, mutect2, varscan2
- STAC2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 152/326 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61065758; called by muse, mutect2
- STK11IP | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1481027258, COSV55248160; called by muse, mutect2, varscan2
- STXBP5L | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56519327; called by muse, mutect2, varscan2
- SUSD2 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 310/646 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64204614; called by muse, mutect2, varscan2
- SYDE2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 259/495 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs866665388; called by muse, mutect2, varscan2
- SYNE2 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 197/387 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as rs750565287; called by muse, mutect2, varscan2
- SYT9 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs866149392; called by muse, mutect2, varscan2
- TAFA2 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 118/253 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV69186024, COSV69186246; called by muse, mutect2, varscan2
- TAS2R16 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 182/328 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV50796811; called by muse, mutect2, varscan2
- TBC1D2 | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59782919; called by muse, mutect2, varscan2
- TCF4 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CD120294, COSV61906793; called by muse, mutect2, varscan2
- TECTA | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 150/294 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1254904390, COSV50792410, COSV99880540; called by muse, mutect2, varscan2
- TEX13C | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 212/213 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs962433761; called by muse, mutect2, varscan2
- TEX15 | c.814C>T p.P272S (on ENST00000256246; = p.P655S on NM_001350162.2) | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV56352351; called by muse, mutect2, varscan2
- TEX36 | c.54C>T p.F18= | Splice Region (SNP) | VAF 142/142 reads (100%) | catalogued as COSV64314608; called by muse, mutect2, varscan2
- TG | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 136/438 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs142629621; called by muse, mutect2, varscan2
- TGM4 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 194/352 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1045568029, COSV56096137; called by muse, mutect2
- THEMIS | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 334/334 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as rs144830633; called by muse, mutect2, varscan2
- THSD7B | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 170/399 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as rs936570414; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 258/520 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TINAG | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 254/509 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248163763; called by muse, mutect2, varscan2
- TMEM132B | c.2950C>T p.L984F | Missense Mutation (SNP) | VAF 179/334 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168954, COSV54773434; called by muse, mutect2, varscan2
- TMEM143 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 247/533 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53156635; called by muse, mutect2, varscan2
- TMPRSS11D | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs760967680, COSV52227086; called by muse, mutect2, varscan2
- TNFRSF8 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 134/286 reads (47%) | catalogued as rs868408646, COSV55796948; called by muse, varscan2
- TNRC18 | c.8458C>T p.R2820C | Missense Mutation (SNP) | VAF 140/907 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs759777568, COSV100079182; called by muse, mutect2, varscan2
- TNXB | c.8417G>A p.R2806K (on ENST00000647633; = p.R2559K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 279/646 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.511); catalogued as COSV100926418; called by muse, mutect2, varscan2
- TONSL | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 185/447 reads (41%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.727); catalogued as rs777660488, COSV68049424; called by muse, mutect2, varscan2
- TPM4 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 141/335 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs377593044; called by muse, mutect2, varscan2
- TPO | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 370/774 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.226); catalogued as rs1483637719, COSV61104969; called by muse, mutect2, varscan2
- TPR | c.6740C>T p.S2247F | Missense Mutation (SNP) | VAF 188/422 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66604232; called by muse, mutect2, varscan2
- TPTE | c.367C>T p.P123S (on ENST00000618007 / NM_199261.4; = p.P105S on NM_199259.4) | Missense Mutation (SNP) | VAF 156/692 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs778635152; called by muse, mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by muse, mutect2, varscan2
- TPTE2 | c.643G>A p.D215N (on ENST00000400230 / NM_199254.2; = p.D138N on NM_130785.3) | Missense Mutation (SNP) | VAF 114/165 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV55022571; called by muse, mutect2, varscan2
- TRA2A | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 226/438 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1349998404, COSV51716241; called by muse, mutect2, varscan2
- TRIM15 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 425/910 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs1458419314; called by muse, mutect2, varscan2
- TRIM36 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 219/311 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs759529085, COSV56688556; called by muse, mutect2, varscan2
- TRIM48 | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 203/421 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs573313143; called by muse, mutect2, varscan2
- TRIM64C | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1180618492; called by muse, mutect2, varscan2
- TRIM64C | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs574326954; called by muse, mutect2, varscan2
- TRIML2 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 200/571 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58717127; called by muse, mutect2, varscan2
- TRIOBP | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 397/846 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1263067680; called by muse, mutect2, varscan2
- TRPC5 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as rs1338428886; called by muse, mutect2, varscan2
- TRPC6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 187/347 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs375722338; called by muse, mutect2, varscan2
- TRPV5 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 256/503 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867533205, COSV54689960; called by muse, mutect2, varscan2
- TRPV5 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 142/366 reads (39%) | catalogued as rs141452078, COSV99520344; called by muse, mutect2, varscan2
- TRRAP | c.4240G>A p.E1414K | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs782581231, COSV62842841; called by muse, mutect2, varscan2
- TSHB | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as rs868014070, COSV56655954; called by muse, mutect2, varscan2
- TSHZ2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 245/511 reads (48%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.797); catalogued as rs367709263; called by muse, mutect2, varscan2
- TTN | c.27476G>A p.G9159E (on ENST00000591111; = p.G8232E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/342 reads (57%) | PolyPhen probably damaging (1); catalogued as COSV60418761; called by muse, mutect2, varscan2
- TXNDC16 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs997101966, COSV55984584; called by muse, mutect2, varscan2
- TXNDC2 | c.836C>T p.P279L (on ENST00000306084 / NM_001098529.2; = p.P212L on NM_032243.6) | Missense Mutation (SNP) | VAF 544/729 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1567882693; called by muse, mutect2, varscan2
- UGT1A1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 208/461 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769666128; called by muse, mutect2, varscan2
- UGT2B28 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 148/159 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV59434729; called by muse, mutect2, varscan2
- UGT2B4 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 141/336 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV59315992; called by muse, mutect2, varscan2
- UPB1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 175/371 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384941421; called by muse, mutect2, varscan2
- UROC1 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 375/774 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52033242; called by muse, mutect2, varscan2
- USH2A | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 134/319 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs370653547; called by muse, mutect2, varscan2
- USHBP1 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 345/576 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as rs1213879437; called by muse, mutect2, varscan2
- USP14 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1209771623, COSV99864332; called by muse, mutect2, varscan2
- USP17L7 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.136); catalogued as rs1456634017; called by muse, mutect2, varscan2
- USP49 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 224/458 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762070875; called by muse, mutect2, varscan2
- UTP20 | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 121/320 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs760523413; called by muse, mutect2
- VAV1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 182/347 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as rs368628133; called by muse, mutect2, varscan2
- VIPR2 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 131/207 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866584688, COSV51109854; called by muse, mutect2, varscan2
- VPS13B | c.9412C>T p.R3138C | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as rs766896327, COSV62137007; called by muse, mutect2, varscan2
- VPS37C | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 311/636 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs1336499862; called by muse, mutect2
- VWA5B2 | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 351/725 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1273993135, COSV56610960; called by muse, mutect2, varscan2
- VWF | c.5558G>A p.R1853Q | Missense Mutation (SNP) | VAF 193/440 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV54613411; called by muse, mutect2, varscan2
- WDFY4 | c.7087G>A p.E2363K | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs754647092; called by muse, mutect2, varscan2
- WFDC8 | c.608G>C p.R203P | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV51489847; called by muse, mutect2, varscan2
- WIPF3 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 288/528 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs772814388; called by muse, mutect2, varscan2
- WNT2B | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 165/305 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV56675934; called by muse, mutect2, varscan2
- WNT5B | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 178/344 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV60198053; called by muse, mutect2, varscan2
- XYLB | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 141/384 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs1425247486; called by muse, mutect2, varscan2
- ZC3H11B | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 158/359 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161877769, COSV65844808; called by muse, mutect2, varscan2
- ZFPM2 | c.2711G>A p.S904N | Missense Mutation (SNP) | VAF 220/475 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV65874513; called by muse, mutect2, varscan2
- ZFR2 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 138/341 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.348); catalogued as rs1379650054; called by muse, mutect2, varscan2
- ZNF142 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 286/570 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV63720056; called by muse, mutect2, varscan2
- ZNF212 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 110/359 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.328); catalogued as rs1222731093; called by muse, mutect2, varscan2
- ZNF224 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 196/352 reads (56%) | catalogued as rs761291888, COSV61242352; called by muse, mutect2, varscan2
- ZNF239 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs925772791; called by muse, mutect2, varscan2
- ZNF276 | c.263C>T p.S88L (on ENST00000443381 / NM_001113525.2; = p.S13L on NM_152287.4) | Missense Mutation (SNP) | VAF 276/425 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV57069310; called by muse, mutect2, varscan2
- ZNF317 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 220/423 reads (52%) | catalogued as rs201883092; called by muse, mutect2, varscan2
- ZNF334 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 221/434 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs1424100806, COSV61618542; called by muse, mutect2, varscan2
- ZNF362 | c.39-1G>A p.X13_splice | Splice Site (SNP) | VAF 231/498 reads (46%) | catalogued as COSV65031377; called by muse, mutect2, varscan2
- ZNF362 | c.39G>A p.R13= | Splice Region (SNP) | VAF 235/505 reads (47%) | catalogued as rs1557792041; called by muse, mutect2, varscan2
- ZNF407 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 291/385 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1218481598; called by muse, mutect2, varscan2
- ZNF407 | c.5810G>A p.G1937E | Missense Mutation (SNP) | VAF 467/621 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs1249639445; called by muse, mutect2, varscan2
- ZNF408 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 367/756 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1375969701; called by muse, mutect2, varscan2
- ZNF469 | c.11609G>A p.G3870E (on ENST00000437464; = p.G3898E on NM_001367624.2) | Missense Mutation (SNP) | VAF 341/523 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1349511313; called by muse, mutect2, varscan2
- ZNF543 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.415); catalogued as COSV100386618; called by muse, mutect2, varscan2
- ZNF556 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 215/454 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs367809549; called by muse, mutect2, varscan2
- ZNF573 | c.1978C>T p.H660Y (on ENST00000536220 / NM_001172692.1; = p.H602Y on NM_152360.3) | Missense Mutation (SNP) | VAF 124/246 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866009263, COSV59827994; called by muse, mutect2, varscan2
- ZNF653 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 216/525 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758886733, COSV99542449; called by muse, mutect2, varscan2
- ZNF675 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 159/274 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV63097235; called by muse, mutect2, varscan2
- ZNF675 | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63097571; called by muse, mutect2, varscan2
- ZNF710 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 354/735 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs776778157; called by muse, mutect2, varscan2
- ZNF727 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 165/322 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV70702445; called by muse, mutect2, varscan2
- ZNF804A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs767783310, COSV56437143; called by muse, mutect2, varscan2
- ZNF835 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 210/475 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV73379389; called by muse, mutect2, varscan2
- ZNF837 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 262/646 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1004202339; called by muse, mutect2, varscan2
- ZNF880 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1327622109; called by muse, mutect2, varscan2
- ZNF98 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV63337323; called by muse, mutect2, varscan2
- ZNF99 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 123/302 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs1413971901, COSV68055531, COSV68056054; called by muse, mutect2, varscan2
- ZNF99 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV68056736; called by muse, mutect2, varscan2
- ZUP1 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 73/73 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63945873; called by muse, mutect2, varscan2
- ABCA13 | c.13231C>T p.H4411Y | Missense Mutation (SNP) | VAF 142/266 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, varscan2
- ABCA4 | c.5864T>A p.V1955E | Missense Mutation (SNP) | VAF 163/332 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ABCB11 | c.3156del p.Q1053Nfs*44 | Frame Shift Del (DEL) | VAF 130/556 reads (23%) | called by mutect2, pindel, varscan2
- ABCC11 | c.3662T>G p.I1221S | Missense Mutation (SNP) | VAF 184/422 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABHD13 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ABHD6 | c.105A>G p.I35M | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- AC013470.2 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 69/402 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- AC099489.1 | c.4094G>A p.R1365K | Missense Mutation (SNP) | VAF 240/526 reads (46%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.961); called by muse, mutect2
- ACAN | c.4585C>T p.P1529S | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ACSM2B | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 181/410 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAM9 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADAMTS13 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 196/196 reads (100%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ADGRG6 | c.3614C>T p.S1205L | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.1149G>A p.M383I (on ENST00000506720 / NM_001322402.2; = p.M315I on NM_015236.6) | Missense Mutation (SNP) | VAF 117/330 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGGF1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 94/125 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHDC1 | c.3500C>T p.S1167F | Missense Mutation (SNP) | VAF 231/437 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK | c.15421C>T p.P5141S | Missense Mutation (SNP) | VAF 200/473 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AL645922.1 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 157/391 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ALMS1 | c.11576C>T p.S3859F | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALPK3 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 291/632 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKAR | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 135/301 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKFN1 | c.3209C>T p.S1070L (on ENST00000653862; = p.S923L on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 733/735 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD18B | c.2667G>A p.M889I | Missense Mutation (SNP) | VAF 100/101 reads (99%) | SIFT tolerated (0.3); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ANKRD31 | c.2089A>G p.K697E | Missense Mutation (SNP) | VAF 92/130 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- ANKRD35 | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 279/523 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ANKRD62 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANO3 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANXA9 | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 198/420 reads (47%) | called by muse, mutect2, varscan2
- APC | c.7921A>G p.K2641E | Missense Mutation (SNP) | VAF 102/172 reads (59%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- APOA2 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 193/385 reads (50%) | called by muse, mutect2, varscan2
- APOA4 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 269/649 reads (41%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- APOH | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- APOH | c.955A>T p.T319S | Missense Mutation (SNP) | VAF 315/315 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AQP10 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 172/326 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP2 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ARHGAP25 | c.1162G>A p.D388N (on ENST00000409202 / NM_001007231.3; = p.D380N on NM_014882.3) | Missense Mutation (SNP) | VAF 201/425 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by muse, mutect2
- ARHGAP29 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP45 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 243/411 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF7 | c.604G>A p.E202K (on ENST00000375741 / NM_001113511.2; = p.E24K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1A | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 299/587 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ARID4B | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ARIH2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ARMC4 | c.451T>A p.L151I | Missense Mutation (SNP) | VAF 138/138 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARNTL2 | c.931T>C p.F311L | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ASB14 | c.659C>G p.P220R (on ENST00000389601; = p.P219R on NM_001142733.3) | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ASMTL | c.934T>G p.L312V | Missense Mutation (SNP) | VAF 343/424 reads (81%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ATN1 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 295/662 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ATP2A1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 215/454 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATXN10 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 186/421 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AUTS2 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 150/288 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- B3GALT1 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 210/456 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- BAZ1A | c.2788T>C p.C930R | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- BDH1 | c.110_113del p.S37Lfs*50 | Frame Shift Del (DEL) | VAF 98/541 reads (18%) | called by mutect2, pindel, varscan2
- BEST3 | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 227/445 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BICRA | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 314/739 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BIRC6 | c.2402A>G p.H801R | Missense Mutation (SNP) | VAF 193/409 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BRF1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 344/675 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BRINP1 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 265/265 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRWD3 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- BTBD11 | c.2306C>T p.A769V (on ENST00000280758 / NM_001018072.2; = p.A306V on NM_001017523.2) | Missense Mutation (SNP) | VAF 273/487 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BTBD8 | c.1345A>C p.I449L | Missense Mutation (SNP) | VAF 267/494 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- C19orf47 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 183/434 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- C1orf127 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 176/393 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C1orf189 | c.196_204+13del p.X66_splice | Splice Site (DEL) | VAF 133/295 reads (45%) | called by mutect2, pindel, varscan2
- C2CD2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 206/455 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- C3 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C3 | c.1121T>G p.V374G | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C4orf54 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- C6 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 123/200 reads (62%) | called by muse, mutect2, varscan2
- CA3 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 153/314 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CACNA1S | c.4666C>T p.Q1556* | Nonsense Mutation (SNP) | VAF 114/248 reads (46%) | called by muse, mutect2, varscan2
- CACNG3 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 183/381 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CALCOCO1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CALCR | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALCR | c.197A>G p.Q66R | Missense Mutation (SNP) | VAF 117/218 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAMK2A | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 183/294 reads (62%) | called by muse, mutect2, varscan2
- CAMK2G | c.1213C>G p.R405G (on ENST00000423381 / NM_001367518.1; = p.R403G on NM_172171.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 321/323 reads (99%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CAPN1 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CAPN1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 212/415 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CAPN3 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CCBE1 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 109/529 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC117 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 139/300 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CCDC166 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 432/955 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CCDC168 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC85C | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 185/369 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CCL14 | c.81G>A p.R27= (on ENST00000618404 / NM_032963.4; = p.G43= on NM_032962.4) | Splice Region (SNP) | VAF 310/662 reads (47%) | called by muse, mutect2, varscan2
- CCN6 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCT8 | c.802T>A p.F268I | Missense Mutation (SNP) | VAF 177/355 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CCT8 | c.727T>G p.S243A | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CD163 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 184/405 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CD177 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 165/407 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CD28 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 220/425 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CD33 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDH15 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CDHR2 | c.2856G>A p.R952= | Splice Region (SNP) | VAF 158/235 reads (67%) | called by muse, mutect2, varscan2
- CEACAM7 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CELF3 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 266/521 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CELSR3 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 165/427 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CEP126 | c.3041A>T p.D1014V | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CEP250 | c.3292del p.E1098Sfs*9 | Frame Shift Del (DEL) | VAF 143/388 reads (37%) | called by mutect2, pindel, varscan2
- CES4A | c.1522C>T p.P508S (on ENST00000648724 / NM_001364782.1; = p.T440= on NM_173815.7) | Missense Mutation (SNP) | VAF 107/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP54 | c.8669C>T p.S2890L | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CFAP57 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHL1 | c.553A>T p.K185* | Nonsense Mutation (SNP) | VAF 148/266 reads (56%) | called by mutect2, varscan2
- CHST2 | c.750del p.F250Lfs*52 | Frame Shift Del (DEL) | VAF 366/864 reads (42%) | called by mutect2, pindel, varscan2
- CHST9 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CIB3 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 284/534 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CLEC10A | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CLEC10A | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT tolerated (0.75); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CLEC20A | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 129/317 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 167/321 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMTM8 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 139/271 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CNTN5 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 127/284 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COBLL1 | c.2915C>T p.P972L (on ENST00000392717; = p.P934L on NM_014900.5) | Missense Mutation (SNP) | VAF 228/504 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- COBLL1 | c.1208C>T p.P403L (on ENST00000392717; = p.P365L on NM_014900.5) | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL22A1 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 225/519 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A1 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 233/508 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- COL6A5 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 128/269 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL9A1 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT tolerated (0.59); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- COL9A1 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A2 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 321/651 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CPAMD8 | c.1011C>T p.I337= (on ENST00000651564; = p.I290= on NM_015692.5) | Splice Region (SNP) | VAF 121/280 reads (43%) | called by muse, mutect2, varscan2
- CPED1 | c.249G>A p.K83= | Splice Region (SNP) | VAF 71/147 reads (48%) | called by muse, mutect2, varscan2
- CPHXL | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 224/431 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CPM | c.1256T>C p.L419S | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
1,189 further variants in this file (504 protein-altering or splice-affecting, 605 silent, 80 other) are not listed here.
